Somatic mutation profile of tumor specimen BA2497D (aliquot aq-BA2497D) from BEATAML1.0 case 2517, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute monoblastic and monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.9 years (26,267 days).
Specimen BA2497D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95812fac-1563-46d8-ad20-5d59fb82ae8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2062D (Solid Tissue Normal), aliquot aq-BA2062D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03355598-7772-4281-9bb4-eb88f208bb2e

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX5 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- ANKRD35 | c.2677C>A p.R893S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2
- CHRM4 | c.314G>T p.C105F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRG4 | c.3311C>A p.T1104K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRERF1 | c.1756G>T p.V586L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- TDRD15 | c.456G>T p.V152= | Silent (SNP) | VAF 28/158 reads (18%) | called by mutect2, varscan2
- TMIGD3 | c.558G>T p.G186= (on ENST00000369717 / NM_001081976.2; = p.G267= on NM_020683.7) | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- TRPM2 | c.747C>A p.R249= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- HECTD4 | c.3442-29G>T | Intron (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- LMF1 | c.193+6696C>T | Intron (SNP) | VAF 68/244 reads (28%) | catalogued as rs545843210; called by muse, mutect2, varscan2
